TARGET case TARGET-20-D84-EC-CBFA2T3_GLIS2-2 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/795ffb0b-1981-404c-afdc-c4a755696d14

Biospecimens (1 sample)
- Sample TARGET-20-D84-EC-CBFA2T3_GLIS2-2-85: Sample type: Next Generation Cancer Model; Tissue type: Tumor.
